Somatic mutation profile of tumor specimen MP2PRT-PAPSHF-TMP1-A (aliquot MP2PRT-PAPSHF-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPSHF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (861 days).
Specimen MP2PRT-PAPSHF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f8310d4-928e-42c0-bf22-86efcb2970b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSHF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSHF-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e521bfb-15be-4b8d-b44d-3e78c637cfe2

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 57/245 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.7270G>A p.E2424K | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as rs775802513; called by muse, mutect2, varscan2
- EIF4EBP2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs750591080, COSV100947032; called by muse, mutect2
- KCNT1 | c.2638G>A p.A880T (on ENST00000488444; = p.A899T on NM_020822.3) | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs778647834, COSV53702134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLF1 | c.87+1G>A p.X29_splice | Splice Site (SNP) | VAF 97/244 reads (40%) | called by muse, mutect2, varscan2
- POTEC | c.1496A>C p.K499T | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- TRDV2 | chr14:22423036 TGACACCCA>CCAGTATGGGTCCCCATCCCTG | Missense Mutation (INS) | VAF 30/150 reads (20%) | called by pindel, varscan2*
- WNT5B | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- HOOK2 | c.264G>A p.A88= | Silent (SNP) | VAF 116/246 reads (47%) | catalogued as rs767313667, COSV53401336; called by muse, mutect2, varscan2
- ZNF423 | c.363G>A p.A121= (on ENST00000563137 / NM_001379286.1; = p.A113= on NM_015069.4) | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs369376307; ClinVar: likely benign; called by muse, mutect2
